Somatic mutation profile of tumor specimen TARGET-30-PAUGVZ-01A (aliquot TARGET-30-PAUGVZ-01A-01D) from TARGET case TARGET-30-PAUGVZ, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 4.4 years (1,614 days).
Specimen TARGET-30-PAUGVZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d059c0a1-9eea-4afe-b82e-20cdaae50d09.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUGVZ-10A (Blood Derived Normal), aliquot TARGET-30-PAUGVZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/821bafc6-91f1-46b0-ae8c-a49077fec5d3

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'Flank 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USP6 | c.224G>A p.S75N | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.066); catalogued as rs1344979661, COSV51476196; called by muse, mutect2, varscan2
- TET2 | chr4:105146796 C>G | 5'Flank (SNP) | VAF 8/21 reads (38%) | catalogued as rs748541597, COSV54399402; called by muse, mutect2, varscan2
